CCDI case PBCHJK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c96d6d36-753f-4aff-87d3-a9eb4887a8a9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.1 years (4,069 days).

Biospecimens (3 samples)
- Sample 0DRZIN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRZIZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRZJJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
